Somatic mutation profile of tumor specimen TCGA-DK-A1AF-01A (aliquot TCGA-DK-A1AF-01A-11D-A13W-08) from TCGA case TCGA-DK-A1AF, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 84.6 years (30,914 days).
Specimen TCGA-DK-A1AF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c3c2d0c2-10b1-4ac3-a1a0-a1faadaeabd8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DK-A1AF-10A (Blood Derived Normal), aliquot TCGA-DK-A1AF-10A-01D-A13W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a8613684-86e7-4e65-876e-2a27a628e2b3

The open-access MAF lists 90 somatic variants for this specimen: 71 protein-altering or splice-affecting, 18 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 62, Silent 18, Nonsense Mutation 6, Intron 1, Splice Region 1, Translation Start Site 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- STAG2 | c.646C>T p.R216* | Nonsense Mutation (SNP) | VAF 24/380 reads (6%) | hotspot (GDC flag); catalogued as COSV54350685, COSV54365974; called by muse, mutect2
- A2ML1 | c.4022C>A p.P1341Q | Missense Mutation (SNP) | VAF 18/308 reads (6%) | SIFT tolerated (0.62); PolyPhen benign (0.031); catalogued as rs376705356, COSV55298734; called by muse, mutect2
- ABCC10 | c.718G>A p.E240K (on ENST00000372530 / NM_001198934.2; = p.E197K on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as COSV55094053; called by muse, mutect2
- AC008878.1 | c.109C>T p.Q37* | Nonsense Mutation (SNP) | VAF 6/102 reads (6%) | catalogued as COSV51182137; called by muse, mutect2
- ADAT1 | c.85C>T p.H29Y | Missense Mutation (SNP) | VAF 6/91 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.124); catalogued as COSV57188534; called by muse, mutect2
- ARHGAP19 | c.92C>G p.S31C | Missense Mutation (SNP) | VAF 5/98 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.518); catalogued as COSV57396032, COSV57396164; called by muse, mutect2
- BMT2 | c.544G>C p.E182Q | Missense Mutation (SNP) | VAF 8/160 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.033); catalogued as COSV51781125; called by muse, mutect2
- C12orf66 | c.967G>A p.E323K | Missense Mutation (SNP) | VAF 14/202 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.341); catalogued as COSV61324781; called by muse, mutect2
- C8B | c.1114C>G p.L372V | Missense Mutation (SNP) | VAF 7/132 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.16); catalogued as COSV64779705; called by muse, mutect2
- CCL23 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs201639291; called by muse, mutect2
- CHUK | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 8/103 reads (8%) | SIFT tolerated (0.38); PolyPhen benign (0.251); catalogued as COSV64918749; called by muse, mutect2
- COPE | c.232G>A p.A78T | Missense Mutation (SNP) | VAF 9/210 reads (4%) | SIFT tolerated (0.35); PolyPhen benign (0.01); catalogued as COSV53232500; called by muse, mutect2
- DCLK2 | c.556G>A p.E186K | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.101); catalogued as COSV56212346; called by muse, mutect2, varscan2
- DEPDC7 | c.1319G>A p.G440E (on ENST00000241051 / NM_001077242.2; = p.G431E on NM_139160.2) | Missense Mutation (SNP) | VAF 20/153 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV53809355; called by muse, mutect2, varscan2
- DOP1A | c.2915C>T p.S972F | Missense Mutation (SNP) | VAF 16/222 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV52718272; called by muse, mutect2
- EXPH5 | c.3404G>T p.G1135V | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.625); catalogued as COSV56208405; called by muse, mutect2
- EXTL3 | c.2017G>A p.E673K | Missense Mutation (SNP) | VAF 7/113 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55040514; called by muse, mutect2
- EZR | c.1077G>C p.K359N | Missense Mutation (SNP) | VAF 10/200 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.195); catalogued as COSV61456177; called by muse, mutect2
- F2R | c.879C>G p.I293M | Missense Mutation (SNP) | VAF 8/159 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV59929159, COSV59929409, COSV59930196; called by muse, mutect2
- F8 | c.886C>T p.L296F | Missense Mutation (SNP) | VAF 17/226 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.299); catalogued as CM073053, COSV64278799; called by muse, mutect2
- FASTKD1 | c.904C>T p.H302Y | Missense Mutation (SNP) | VAF 21/296 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs1199588714, COSV70007299; called by muse, mutect2
- FAT2 | c.8887G>C p.E2963Q | Missense Mutation (SNP) | VAF 4/83 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.359); catalogued as COSV55829681; called by muse, mutect2
- FLG | c.11744C>G p.S3915C | Missense Mutation (SNP) | VAF 6/117 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV64239494, COSV64249553; called by muse, mutect2
- HELZ | c.1811A>T p.H604L | Missense Mutation (SNP) | VAF 8/176 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62381008; called by muse, mutect2
- IQCG | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 39/596 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54566324; called by muse, mutect2
- KCNK2 | c.17C>T p.S6L | Missense Mutation (SNP) | VAF 11/111 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.32); catalogued as rs766967584, COSV101222263, COSV67204276, COSV67204289; called by muse, mutect2
- KCTD11 | c.448C>G p.H150D (on ENST00000333751 / NM_001363642.1; = p.H111D on NM_001002914.2) | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.113); catalogued as COSV50142039; called by muse, mutect2
- KDR | c.2817G>A p.K939= | Splice Region (SNP) | VAF 9/117 reads (8%) | catalogued as COSV55776521; called by muse, mutect2
- LAMB3 | c.3352G>A p.E1118K | Missense Mutation (SNP) | VAF 13/221 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.439); catalogued as COSV50526775; called by muse, mutect2
- LAMP3 | c.1081C>G p.Q361E | Missense Mutation (SNP) | VAF 27/349 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV55617070; called by muse, mutect2
- LRP1B | c.4015G>A p.G1339S | Missense Mutation (SNP) | VAF 16/178 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV67208438; called by muse, mutect2
- LRRC7 | c.2513G>A p.R838K (on ENST00000651989 / NM_001370785.2; = p.R805K on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/206 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.236); catalogued as COSV50630191; called by muse, mutect2
- MAP6 | c.2179C>G p.Q727E | Missense Mutation (SNP) | VAF 27/263 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.058); catalogued as COSV59077964; called by muse, mutect2, varscan2
- MDC1 | c.5989G>A p.E1997K | Missense Mutation (SNP) | VAF 16/235 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.424); catalogued as COSV64527709; called by muse, mutect2
- MED13 | c.6123G>C p.Q2041H | Missense Mutation (SNP) | VAF 9/113 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.832); catalogued as COSV101181445, COSV67267133; called by muse, mutect2
- METTL8 | c.512C>T p.S171F | Missense Mutation (SNP) | VAF 15/306 reads (5%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.494); catalogued as COSV64551866; called by muse, mutect2
- MLXIPL | c.2092G>C p.E698Q | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV57670476; called by muse, mutect2
- MYOF | c.1633C>T p.L545F | Missense Mutation (SNP) | VAF 8/184 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV63710792; called by muse, mutect2
- NECTIN3 | c.1036C>T p.Q346* | Nonsense Mutation (SNP) | VAF 6/80 reads (8%) | catalogued as COSV60553441; called by muse, mutect2
- NPAT | c.1756G>A p.E586K | Missense Mutation (SNP) | VAF 15/276 reads (5%) | SIFT tolerated (0.69); PolyPhen benign (0.023); catalogued as COSV53721858; called by muse, mutect2
- PLEKHM3 | c.1246G>T p.D416Y | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101216757; called by muse, mutect2
- PSMD4 | c.847G>C p.E283Q | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100924649, COSV64394112; called by muse, mutect2, varscan2
- RLBP1 | c.490G>C p.E164Q | Missense Mutation (SNP) | VAF 8/141 reads (6%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.737); catalogued as COSV51529442; called by muse, mutect2
- RNF125 | c.165-1G>T p.X55_splice | Splice Site (SNP) | VAF 26/451 reads (6%) | catalogued as COSV54186936; called by muse, mutect2
- SAMD9 | c.1093G>C p.D365H | Missense Mutation (SNP) | VAF 11/219 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.293); catalogued as COSV101180138, COSV66077561; called by muse, mutect2
- SLC17A5 | c.812G>C p.R271T | Missense Mutation (SNP) | VAF 13/118 reads (11%) | SIFT tolerated (0.48); PolyPhen benign (0.005); catalogued as COSV63288861; called by muse, mutect2, varscan2
- SPHKAP | c.2334C>A p.H778Q | Missense Mutation (SNP) | VAF 32/510 reads (6%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV60894609; called by muse, mutect2
- TAS2R9 | c.487G>C p.E163Q | Missense Mutation (SNP) | VAF 13/120 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0.381); catalogued as COSV53688760, COSV53689914; called by muse, mutect2, varscan2
- TEX37 | c.196G>C p.D66H | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.919); catalogued as COSV57556923; called by muse, mutect2
- UGP2 | c.1258G>A p.E420K | Missense Mutation (SNP) | VAF 12/230 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs1319421745, COSV61430340; called by muse, mutect2
- VWA7 | c.1701C>G p.F567L | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT tolerated (0.44); PolyPhen benign (0.013); catalogued as COSV65174185; called by muse, mutect2
- ZNF358 | c.211C>A p.L71M | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.884); catalogued as COSV51182139; called by muse, mutect2
- ZNF429 | c.1828C>G p.Q610E | Missense Mutation (SNP) | VAF 8/111 reads (7%) | SIFT tolerated (0.6); PolyPhen benign (0.036); catalogued as COSV61919140; called by muse, mutect2
- ZNF491 | c.152C>T p.S51F | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV60058935; called by muse, mutect2
- ZNF502 | c.1084C>G p.Q362E | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.209); catalogued as COSV56075167; called by muse, mutect2
- ZNF615 | c.1918A>G p.I640V | Missense Mutation (SNP) | VAF 16/358 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV65034939; called by muse, mutect2
- ZNF630 | c.1014G>C p.Q338H | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV52098249; called by muse, mutect2
- ATAD1 | c.847G>C p.D283H | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.808); called by muse, mutect2
- CDC14B | c.616G>A p.E206K | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); called by muse, mutect2
- CHST2 | c.1213A>G p.T405A | Missense Mutation (SNP) | VAF 5/87 reads (6%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.525); called by muse, mutect2
- DGKQ | c.2674G>A p.E892K | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- DNAJC3 | c.439C>T p.Q147* | Nonsense Mutation (SNP) | VAF 9/104 reads (9%) | called by muse, mutect2
- ERF | c.65C>G p.P22R | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FASTKD1 | c.602C>A p.S201Y | Missense Mutation (SNP) | VAF 4/55 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.287); called by muse, mutect2
- NCKAP1L | c.1441G>C p.E481Q | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.243); called by muse, mutect2
- PBX1 | c.349G>A p.V117M | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.995); called by muse, mutect2
- PRSS45P | c.779C>T p.S260F | Missense Mutation (SNP) | VAF 10/190 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.034); called by muse, mutect2
- SLC4A10 | c.1255G>C p.E419Q (on ENST00000446997 / NM_001354461.2; = p.E389Q on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- WDR13 | c.864G>A p.M288I | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZKSCAN3 | c.1388G>A p.W463* | Nonsense Mutation (SNP) | VAF 6/68 reads (9%) | called by muse, mutect2
- ZNF429 | c.1481C>G p.S494* | Nonsense Mutation (SNP) | VAF 9/69 reads (13%) | called by muse, mutect2, varscan2
- C12orf66 | c.711G>A p.K237= | Silent (SNP) | VAF 9/80 reads (11%) | catalogued as rs1395469637, COSV61324790; called by muse, mutect2, varscan2
- CLRN2 | c.639C>A p.L213= | Silent (SNP) | VAF 9/126 reads (7%) | catalogued as COSV71825295; called by muse, mutect2
- DNAH10 | c.8145C>T p.F2715= (on ENST00000409039; = p.F2654= on NM_207437.3) | Silent (SNP) | VAF 20/318 reads (6%) | catalogued as COSV69001865; called by muse, mutect2
- ESPL1 | c.162G>A p.L54= | Silent (SNP) | VAF 7/110 reads (6%) | catalogued as COSV57763422; called by muse, mutect2
- FANCM | c.5208G>C p.L1736= | Silent (SNP) | VAF 23/277 reads (8%) | catalogued as COSV57506710; called by muse, mutect2
- FOXK1 | c.984G>C p.L328= | Silent (SNP) | VAF 8/80 reads (10%) | catalogued as COSV61068826; called by muse, mutect2
- FRAS1 | c.3003C>G p.L1001= | Silent (SNP) | VAF 11/111 reads (10%) | catalogued as COSV53648933; called by muse, mutect2
- INSIG1 | c.658C>T p.L220= | Silent (SNP) | VAF 10/128 reads (8%) | catalogued as rs1430232198, COSV60919643, COSV60921239; called by muse, mutect2
- LRRC46 | c.396G>A p.Q132= | Silent (SNP) | VAF 6/80 reads (8%) | catalogued as COSV51637412; called by muse, mutect2
- NAT10 | c.612C>G p.L204= | Silent (SNP) | VAF 14/89 reads (16%) | catalogued as COSV57666317; called by muse, mutect2
- NCKAP1L | c.294C>T p.V98= | Silent (SNP) | VAF 14/215 reads (7%) | catalogued as rs988945657, COSV53212446; called by muse, mutect2
- PFAS | c.2103G>A p.L701= | Silent (SNP) | VAF 3/13 reads (23%) | called by muse, mutect2
- PM20D1 | c.108G>A p.A36= | Silent (SNP) | VAF 5/72 reads (7%) | catalogued as rs1285078700, COSV65649709; called by muse, mutect2
- RIMS2 | c.1449C>G p.L483= (on ENST00000666250 / NM_001348490.2; = p.L291= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 8/84 reads (10%) | catalogued as COSV51724650, COSV99170243; called by muse, mutect2
- SLC25A6 | c.243C>T p.Y81= | Silent (SNP) | VAF 12/232 reads (5%) | catalogued as COSV67318022; called by muse, mutect2
- TCP11 | c.693G>A p.Q231= (on ENST00000512012; = p.Q169= on NM_018679.5) | Silent (SNP) | VAF 50/652 reads (8%) | catalogued as COSV55136060; called by muse, mutect2
- USP51 | c.1086G>C p.L362= | Silent (SNP) | VAF 16/256 reads (6%) | catalogued as COSV72351865; called by muse, mutect2
- VPS54 | c.267C>T p.F89= | Silent (SNP) | VAF 23/323 reads (7%) | catalogued as COSV55445376; called by muse, mutect2
- MACF1 | c.15832-9636G>C | Intron (SNP) | VAF 4/29 reads (14%) | catalogued as COSV57144701; called by muse, mutect2, varscan2
